Somatic mutation profile of tumor specimen ALCH-B1JU-TTP1-A (aliquot ALCH-B1JU-TTP1-A-1-0-D-A714-36) from ALCHEMIST case ALCH-B1JU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.4 years (26,825 days).
Specimen ALCH-B1JU-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7cd1ad1d-7c20-462c-8332-310c00505fef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1JU-NB1-A (Blood Derived Normal), aliquot ALCH-B1JU-NB1-A-1-0-D-A714-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6dbc30c9-416f-4a0b-a1b8-fade11af1d65

The open-access MAF lists 51 somatic variants for this specimen: 34 protein-altering or splice-affecting, 12 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 12, Nonsense Mutation 5, Intron 3, Frame Shift Ins 1, Nonstop Mutation 1, Frame Shift Del 1, Splice Region 1, In Frame Del 1, 5'UTR 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 90/558 reads (16%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- AC244258.1 | n.621A>G | Splice Region (SNP) | VAF 10/90 reads (11%) | catalogued as rs779724434; called by muse, mutect2
- ARID1A | c.5919G>A p.W1973* | Nonsense Mutation (SNP) | VAF 45/441 reads (10%) | catalogued as COSV61391034; called by muse, mutect2, varscan2
- CDCA2 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 50/437 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as rs755408049; called by muse, mutect2, varscan2
- MUC12 | c.3440C>T p.T1147M (on ENST00000379442; = p.T1004M on NM_001164462.1) | Missense Mutation (SNP) | VAF 27/424 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.788); catalogued as rs751046611; called by muse, mutect2
- MYH7B | c.5092C>T p.L1698F | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.444); catalogued as rs1419082471; called by muse, mutect2, varscan2
- OR1B1 | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 6/137 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59171881; called by muse, mutect2
- PPRC1 | c.4216C>T p.R1406* | Nonsense Mutation (SNP) | VAF 31/240 reads (13%) | catalogued as COSV53387403; called by muse, mutect2, varscan2
- PRAMEF27 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 57/321 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as rs1309161806; called by muse, mutect2, varscan2
- SIRT5 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as rs139920526; called by muse, mutect2, varscan2
- SYNE1 | c.1888G>T p.E630* (on ENST00000367255 / NM_182961.4; = p.E637* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 40/777 reads (5%) | catalogued as COSV55012490; called by muse, mutect2
- ACP3 | c.805A>C p.N269H | Missense Mutation (SNP) | VAF 26/386 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); called by muse, mutect2
- ATP6V1B1 | c.1540T>C p.*514Qext*100 | Nonstop Mutation (SNP) | VAF 19/126 reads (15%) | called by muse, mutect2, varscan2
- ATP7B | c.2596A>T p.K866* | Nonsense Mutation (SNP) | VAF 24/591 reads (4%) | called by muse, mutect2
- BAG4 | c.1150A>G p.I384V | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2
- CD34 | c.558dup p.Q187Sfs*9 | Frame Shift Ins (INS) | VAF 46/407 reads (11%) | called by mutect2, pindel, varscan2
- CRB1 | c.2192A>G p.E731G | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- DCLRE1A | c.1061A>T p.D354V | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- DNHD1 | c.6619C>T p.Q2207* | Nonsense Mutation (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- GFRAL | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 16/255 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.521); called by muse, mutect2
- HEATR1 | c.4771G>T p.V1591F | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- LRCH3 | c.1654G>T p.G552W | Missense Mutation (SNP) | VAF 34/466 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); called by muse, mutect2
- OR4K2 | c.752T>G p.F251C | Missense Mutation (SNP) | VAF 46/924 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCLO | c.5498T>C p.I1833T | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- PSME4 | c.3160C>T p.P1054S | Missense Mutation (SNP) | VAF 41/261 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- RAD51AP2 | c.2318A>C p.K773T | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SART3 | c.1437A>T p.E479D (on ENST00000228284; = p.E461D on NM_014706.4) | Missense Mutation (SNP) | VAF 87/435 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- SLC34A2 | c.842_843del p.K281Sfs*10 | Frame Shift Del (DEL) | VAF 46/384 reads (12%) | called by mutect2, pindel, varscan2
- SLTM | c.2452A>G p.R818G | Missense Mutation (SNP) | VAF 37/234 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SRRM1 | c.1990T>C p.S664P | Missense Mutation (SNP) | VAF 47/443 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SRSF4 | c.56A>G p.E19G | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TG | c.7498T>G p.L2500V | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.215); called by muse, mutect2
- TXNDC16 | c.984+1G>T p.X328_splice | Splice Site (SNP) | VAF 16/213 reads (8%) | called by muse, mutect2
- ZIK1 | c.1070G>A p.G357E | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGPAT1 | c.351G>T p.L117= | Silent (SNP) | VAF 31/226 reads (14%) | catalogued as rs992850711; called by muse, mutect2, varscan2
- ATP8B1 | c.603T>A p.R201= | Silent (SNP) | VAF 16/454 reads (4%) | called by muse, mutect2
- CGAS | c.694C>T p.L232= | Silent (SNP) | VAF 24/176 reads (14%) | called by muse, mutect2, varscan2
- COL5A3 | c.4482G>A p.G1494= | Silent (SNP) | VAF 5/54 reads (9%) | called by muse, mutect2
- ITGA2B | c.1851G>A p.L617= | Silent (SNP) | VAF 33/206 reads (16%) | catalogued as rs761664609; called by muse, mutect2, varscan2
- LCA5 | c.504T>C p.I168= | Silent (SNP) | VAF 65/488 reads (13%) | called by muse, mutect2, varscan2
- MOS | c.558G>C p.V186= | Silent (SNP) | VAF 32/598 reads (5%) | called by muse, mutect2
- NFYC | c.1251C>T p.P417= | Silent (SNP) | VAF 15/499 reads (3%) | called by muse, mutect2
- SYNE2 | c.14949A>G p.T4983= | Silent (SNP) | VAF 16/317 reads (5%) | called by muse, mutect2
- TRPS1 | c.315G>A p.V105= (on ENST00000220888 / NM_001330599.2; = p.V118= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 51/311 reads (16%) | called by muse, mutect2, varscan2
- WNK2 | c.4611T>A p.L1537= (on ENST00000297954 / NM_001282394.1; = p.L1500= on NM_006648.3) | Silent (SNP) | VAF 4/24 reads (17%) | called by mutect2, varscan2
- WWP1 | c.1383C>T p.G461= | Silent (SNP) | VAF 44/324 reads (14%) | called by muse, varscan2
- CENPT | c.524-12G>A | Intron (SNP) | VAF 21/147 reads (14%) | catalogued as rs903753802; called by muse, mutect2, varscan2
- GPATCH8 | c.*1802A>G | 3'UTR (SNP) | VAF 76/588 reads (13%) | called by muse, mutect2, varscan2
- SLAIN1 | c.701-1140A>C | Intron (SNP) | VAF 34/278 reads (12%) | called by muse, mutect2, varscan2
- SUCO | c.3266-56A>G | Intron (SNP) | VAF 51/326 reads (16%) | called by muse, mutect2, varscan2
- ZNF487 | c.-326G>A | 5'UTR (SNP) | VAF 6/45 reads (13%) | catalogued as rs574601190; called by muse, varscan2
